Somatic mutation profile of tumor specimen TCGA-AA-3854-01A (aliquot TCGA-AA-3854-01A-01W-0900-09) from TCGA case TCGA-AA-3854, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 71.2 years (26,022 days).
Specimen TCGA-AA-3854-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2aff05d7-56cf-49ea-9454-80127ce3ecc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3854-10A (Blood Derived Normal), aliquot TCGA-AA-3854-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b45f4dd9-7585-45aa-b976-417f900132f5

The open-access MAF lists 150 somatic variants for this specimen: 112 protein-altering or splice-affecting, 34 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 34, Nonsense Mutation 5, Splice Site 2, Splice Region 2, Frame Shift Del 1, In Frame Del 1, RNA 1, Intron 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.5319+1G>A p.X1773_splice | Splice Site (SNP) | VAF 100/116 reads (86%) | catalogued as rs876660175, COSV53775177; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RPS6KA3 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs122454127, CM992428, COSV65387529; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.4535C>T p.T1512M | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs762950948, CM107295, COSV66065817; called by muse, mutect2, varscan2
- ADAMTS12 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 54/830 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201263969, COSV61281223; called by muse, mutect2
- ADAMTS16 | c.1511C>A p.P504H | Missense Mutation (SNP) | VAF 131/160 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56989853; called by muse, mutect2, varscan2
- APC | c.4193del p.S1398Ifs*17 | Frame Shift Del (DEL) | VAF 149/226 reads (66%) | catalogued as COSV57345057, COSV57364642, COSV57394317; called by mutect2, pindel, varscan2
- ARFGEF2 | c.1597C>A p.L533I | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.463); catalogued as COSV100904325; called by muse, mutect2
- ATP13A3 | c.709G>C p.A237P | Missense Mutation (SNP) | VAF 5/122 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV55467676; called by muse, mutect2
- BACH2 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.886); catalogued as rs922695145, COSV57592556; called by muse, mutect2
- BEX5 | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 61/451 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV61328637; called by muse, mutect2, varscan2
- BPIFA3 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs138661121; called by muse, mutect2, varscan2
- BRINP2 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT tolerated (0.27); PolyPhen benign (0.203); catalogued as rs377625274, COSV64179611; called by muse, mutect2, varscan2
- CA3 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs770535043, COSV53409913; called by muse, mutect2, varscan2
- CA9 | c.916A>G p.T306A | Missense Mutation (SNP) | VAF 102/464 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as COSV61406053; called by muse, mutect2, varscan2
- CACNA1E | c.6247C>T p.R2083W (on ENST00000367573 / NM_001205293.3; = p.R2040W on NM_000721.4) | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1337866196, COSV100702838, COSV62389153; called by muse, mutect2, varscan2
- CCDC172 | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100319723, COSV60937783; called by muse, mutect2, varscan2
- CD84 | c.235A>T p.R79* | Nonsense Mutation (SNP) | VAF 48/367 reads (13%) | catalogued as COSV60868372; called by muse, mutect2, varscan2
- CHAD | c.973A>T p.T325S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV51972468; called by muse, mutect2, varscan2
- CHRNB4 | c.980A>C p.H327P | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99929423; called by muse, mutect2
- CPEB4 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV54169818; called by muse, mutect2, varscan2
- DCAF8L1 | c.807A>T p.E269D | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as COSV71595290, COSV71595338; called by muse, mutect2, varscan2
- DCC | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 90/213 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs367734161; called by muse, mutect2, varscan2
- DKK4 | c.584A>G p.D195G | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV55182522; called by muse, mutect2, varscan2
- DNAH11 | c.6565C>T p.R2189* | Nonsense Mutation (SNP) | VAF 30/94 reads (32%) | catalogued as rs778698443, COSV60954805; called by muse, mutect2, varscan2
- ELOA2 | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.028); catalogued as rs754313615, COSV55299180; called by muse, mutect2, varscan2
- ENAM | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 164/351 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs529994198, COSV68535963; called by muse, mutect2, varscan2
- ERG | c.1339G>A p.V447M (on ENST00000398919 / NM_001243428.1; = p.V423M on NM_004449.4) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as rs1363790097, COSV55732213; called by muse, mutect2
- EXOC4 | c.1456A>G p.K486E | Missense Mutation (SNP) | VAF 171/325 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV54098553; called by muse, mutect2, varscan2
- F5 | c.5942C>T p.A1981V | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63123963; called by muse, mutect2, varscan2
- FAM124B | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs766918271, COSV66272083; called by muse, mutect2, varscan2
- FLG | c.7221G>C p.R2407S | Missense Mutation (SNP) | VAF 123/292 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1456743078, COSV64241914; called by muse, mutect2, varscan2
- FLNC | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs374847180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLOT1 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as COSV52543886; called by muse, mutect2, varscan2
- GAB1 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374885566; called by muse, mutect2, varscan2
- GPR139 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1314429704, COSV58502491; called by muse, mutect2, varscan2
- GRP | c.145T>G p.L49V | Missense Mutation (SNP) | VAF 46/393 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56879169; called by muse, mutect2, varscan2
- HECW2 | c.3382C>T p.R1128C | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1419763782, COSV53659845; called by muse, mutect2, varscan2
- HVCN1 | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV54372189; called by muse, mutect2
- IGLL5 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as COSV101138844, COSV66535455; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1837A>T p.N613Y | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.289); catalogued as COSV100147919; called by muse, mutect2
- JKAMP | c.898A>G p.T300A (on ENST00000554271 / NM_001284201.1; = p.T286A on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/190 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV54199546; called by muse, mutect2, varscan2
- KANK4 | c.1068G>T p.L356F | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV62986790; called by muse, mutect2, varscan2
- KCNF1 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54463490, COSV99705832; called by muse, mutect2
- KCNIP4 | c.432T>C p.D144= | Splice Region (SNP) | VAF 98/245 reads (40%) | catalogued as COSV62850101; called by muse, mutect2, varscan2
- KCNK5 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV63988913; called by muse, mutect2, varscan2
- KIF13B | c.3500A>C p.E1167A | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72954400; called by muse, mutect2, varscan2
- KIZ | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV55685042; called by muse, mutect2, varscan2
- LARS1 | c.2671G>A p.V891I (on ENST00000394434 / NM_020117.11; = p.V864I on NM_016460.3) | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV50976312, COSV99198733; called by muse, mutect2, varscan2
- LRAT | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV60477096; called by muse, mutect2, varscan2
- LRIG1 | c.287A>C p.E96A | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV56240157; called by muse, mutect2, varscan2
- LY75-CD302 | c.5560T>C p.Y1854H | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1416682345, COSV52028852; called by muse, mutect2, varscan2
- MAMLD1 | c.18T>A p.S6R | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.625); catalogued as COSV53374994; called by muse, mutect2, varscan2
- MAN2A2 | c.2681G>T p.S894I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV64638302; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as rs947803443, COSV53796704; called by muse, mutect2, varscan2
- MMP19 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.328); catalogued as COSV59451368; called by muse, mutect2, varscan2
- MTOR | c.1712C>T p.T571M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs749766561, COSV63871676; called by muse, mutect2, varscan2
- MTPAP | c.740T>G p.F247C | Missense Mutation (SNP) | VAF 521/1123 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV53933055; called by muse, mutect2, varscan2
- MUC16 | c.18368C>A p.A6123D | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as COSV67466378; called by muse, mutect2, varscan2
- MYEF2 | c.859G>T p.V287F | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1238121474, COSV51047686; called by muse, mutect2, varscan2
- NFAT5 | c.2013C>G p.N671K | Missense Mutation (SNP) | VAF 42/440 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV63027523; called by muse, mutect2
- NID2 | c.498C>G p.Y166* | Nonsense Mutation (SNP) | VAF 57/129 reads (44%) | catalogued as COSV53496481, COSV99357504; called by muse, mutect2, varscan2
- NRAP | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 114/294 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63490616; called by muse, mutect2, varscan2
- OR13C3 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 212/465 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV66165851; called by muse, mutect2, varscan2
- PALB2 | c.2413G>T p.V805F | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs876659475, COSV55165305; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAX3 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.302); catalogued as rs770087251, CD102011, COSV60586905; called by muse, mutect2, varscan2
- PCDH19 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV55260231; called by muse, mutect2, varscan2
- PCDHB13 | c.1527C>G p.D509E | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.925); catalogued as COSV53396635; called by muse, mutect2, varscan2
- PCDHGB4 | c.1906G>A p.V636I | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as rs1328126483, COSV53949039; called by muse, mutect2, varscan2
- PDE1B | c.1508G>C p.G503A | Missense Mutation (SNP) | VAF 58/446 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV54492806; called by muse, mutect2, varscan2
- PDE1B | c.1509C>T p.G503= | Splice Region (SNP) | VAF 60/456 reads (13%) | catalogued as COSV99226428; called by muse, varscan2
- PLEKHA5 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1428990224, COSV54700829; called by muse, mutect2, varscan2
- PPP3CB | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61152220; called by muse, mutect2, varscan2
- PRAMEF17 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 143/351 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1157534354, COSV101068750; called by muse, mutect2, varscan2
- RANBP10 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs758630219, COSV58157678, COSV58157767; called by muse, mutect2, varscan2
- RHOXF2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as rs370729029, COSV65047640; called by muse, mutect2, varscan2
- RICTOR | c.995A>G p.Y332C | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV57122130; called by muse, mutect2, varscan2
- RRM1 | c.2254C>G p.L752V | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV56163285; called by muse, mutect2, varscan2
- RTL8B | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV66954295; called by muse, mutect2, varscan2
- SEC24B | c.1327T>C p.S443P | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747589922, COSV54496126; called by muse, mutect2, varscan2
- SEC63 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1360860173, COSV64599808; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3PXD2A | c.2747G>A p.G916D (on ENST00000369774 / NM_001365079.1; = p.G888D on NM_014631.2) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV60117213; called by muse, mutect2, varscan2
- SHCBP1 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57647609; called by muse, mutect2, varscan2
- SIPA1L2 | c.2443A>G p.N815D | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV53390548; called by muse, mutect2, varscan2
- SLC25A43 | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 91/369 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.129); catalogued as rs937964905, COSV54217887; called by muse, mutect2, varscan2
- SLC35F3 | c.631G>A p.A211T (on ENST00000366617 / NM_001300845.1; = p.A280T on NM_173508.4) | Missense Mutation (SNP) | VAF 234/455 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs773044833, COSV64019679; called by muse, mutect2, varscan2
- SLITRK1 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 9/101 reads (9%) | catalogued as COSV100999999; called by muse, mutect2
- SPAG17 | c.2855G>A p.R952H | Missense Mutation (SNP) | VAF 256/821 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200995274, COSV60455007; called by muse, mutect2, varscan2
- STYXL2 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.251); catalogued as rs150600224; called by muse, mutect2, varscan2
- SYNE1 | c.16229G>A p.R5410Q (on ENST00000367255 / NM_182961.4; = p.R5339Q on NM_033071.3) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs776100963, COSV54983607, COSV99563602; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBC1D31 | c.2307A>T p.E769D | Missense Mutation (SNP) | VAF 13/248 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54866317; called by muse, mutect2
- THOC2 | c.4391G>C p.R1464T | Missense Mutation (SNP) | VAF 72/583 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV55546057, COSV99833839; called by muse, mutect2, varscan2
- TMEM171 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.255); catalogued as rs747220933, COSV55130332; called by muse, mutect2, varscan2
- TNFRSF21 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV57281964; called by muse, mutect2, varscan2
- TNFSF15 | c.596A>C p.K199T | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65010260; called by muse, mutect2, varscan2
- TNN | c.1807C>A p.Q603K | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV53426324; called by muse, mutect2, varscan2
- TSHZ2 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs749729408, COSV61587382; called by muse, mutect2, varscan2
- TTC6 | c.325C>A p.L109I (on ENST00000267368; = p.L1378I on NM_001310135.3) | Missense Mutation (SNP) | VAF 218/463 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.343); catalogued as COSV57449003; called by muse, mutect2, varscan2
- TTN | c.33114A>T p.E11038D (on ENST00000591111; = p.E10111D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/278 reads (10%) | PolyPhen benign (0.013); catalogued as COSV60066141; called by muse, mutect2, varscan2
- USP29 | c.1606A>G p.S536G | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.498); catalogued as COSV54143322, COSV54145910; called by muse, mutect2
- USP43 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1156460406, COSV53302172, COSV53308106; called by muse, mutect2, varscan2
- VIPAS39 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs755163993, COSV58939779; called by muse, mutect2, varscan2
- WDR13 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs868942700, COSV99489451; called by muse, mutect2, varscan2
- WWOX | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs200815431; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZIC3 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748579579, COSV54974090; called by muse, mutect2, varscan2
- ZNF454 | c.1231C>A p.P411T | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60768420; called by muse, mutect2, varscan2
- ZNF536 | c.3535G>A p.D1179N | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs762646976, COSV62820064, COSV62833089; called by muse, mutect2, varscan2
- ZNF766 | c.1317C>A p.Y439* | Nonsense Mutation (SNP) | VAF 44/217 reads (20%) | catalogued as COSV63009548; called by muse, mutect2, varscan2
- ZNF772 | c.1114C>A p.H372N | Missense Mutation (SNP) | VAF 48/407 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58410817; called by muse, mutect2, varscan2
- ZSCAN2 | c.1564C>T p.R522W | Missense Mutation (SNP) | VAF 18/267 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376085668; called by muse, mutect2
- PCDHGC5 | c.986_991del p.A329_M330del | In Frame Del (DEL) | VAF 127/257 reads (49%) | called by mutect2, pindel, varscan2
- TMEM214 | c.1408-19_1433del p.X470_splice | Splice Site (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel
- ADAM12 | c.1068C>T p.F356= | Silent (SNP) | VAF 68/121 reads (56%) | catalogued as rs778190289, COSV64106841; called by muse, mutect2, varscan2
- ATXN7L1 | c.60G>A p.G20= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs781283339, COSV59493054; called by muse, mutect2, varscan2
- BCORL1 | c.2424G>A p.T808= | Silent (SNP) | VAF 40/73 reads (55%) | catalogued as rs138691600, COSV54396533; called by muse, mutect2, varscan2
- CACNG6 | c.678G>T p.G226= (on ENST00000252729 / NM_145814.1; = p.G155= on NM_031897.2) | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV99403498; called by mutect2, varscan2
- CCDC158 | c.1791A>G p.K597= | Silent (SNP) | VAF 48/179 reads (27%) | catalogued as COSV66355996; called by muse, mutect2, varscan2
- CLCA2 | c.75A>G p.E25= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV65287180; called by muse, mutect2, varscan2
- CYP2A13 | c.102T>A p.P34= | Silent (SNP) | VAF 12/302 reads (4%) | catalogued as COSV100386854; called by muse, mutect2
- EFCAB3 | c.1227C>A p.S409= | Silent (SNP) | VAF 32/558 reads (6%) | catalogued as COSV100540298; called by muse, mutect2
- FAM47B | c.1077C>T p.D359= | Silent (SNP) | VAF 78/215 reads (36%) | catalogued as rs770049861, COSV61453958; called by muse, mutect2, varscan2
- GARRE1 | c.1881G>T p.L627= | Silent (SNP) | VAF 49/160 reads (31%) | catalogued as COSV55099303; called by muse, mutect2, varscan2
- GNAT2 | c.150C>A p.V50= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV63554940; called by muse, mutect2, varscan2
- ITGA8 | c.2355G>A p.A785= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs145199076, COSV65225383; called by muse, mutect2, varscan2
- ITGAD | c.3204G>A p.T1068= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs775259972, COSV54931963; called by muse, mutect2, varscan2
- ITGAM | c.2319T>C p.N773= (on ENST00000648685 / NM_001145808.2; = p.N772= on NM_000632.4) | Silent (SNP) | VAF 73/159 reads (46%) | catalogued as COSV54937190; called by muse, mutect2, varscan2
- KLHL4 | c.49C>T p.L17= | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as COSV100909828; called by muse, mutect2
- LRRC17 | c.672C>G p.P224= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as COSV50867999, COSV99978484; called by muse, mutect2
- MED12 | c.4858T>C p.L1620= | Silent (SNP) | VAF 78/202 reads (39%) | catalogued as rs1569482157, COSV61340170; called by muse, mutect2, varscan2
- MYO9A | c.3042G>A p.L1014= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as rs1245471843, COSV61851129; called by muse, varscan2
- NRG1 | c.1350G>A p.S450= (on ENST00000405005 / NM_013964.5; = p.S455= on NM_013956.5) | Silent (SNP) | VAF 80/198 reads (40%) | catalogued as rs752389906, COSV55151817, COSV55159883; called by muse, mutect2, varscan2
- NT5C3B | c.816G>T p.L272= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV54055782; called by muse, mutect2, varscan2
- OXSR1 | c.219T>C p.P73= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV61258722; called by muse, mutect2, varscan2
- PACRG | c.396C>T p.H132= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as rs753948730, COSV61305115; called by muse, mutect2, varscan2
- PCDHB16 | c.2157G>A p.A719= | Silent (SNP) | VAF 38/47 reads (81%) | catalogued as rs781822956, COSV53362338; called by muse, mutect2, varscan2
- PCDHGC5 | c.582G>T p.L194= | Silent (SNP) | VAF 121/269 reads (45%) | catalogued as COSV52752346; called by muse, mutect2, varscan2
- PNMA3 | c.1230C>T p.R410= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs1286177194, COSV100937619; called by muse, mutect2
- PRKCG | c.1104C>G p.A368= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99669191; called by muse, mutect2
- SCN1A | c.5502G>A p.A1834= (on ENST00000303395 / NM_001202435.3; = p.A1823= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/279 reads (9%) | catalogued as rs754566611, COSV57670336; called by muse, mutect2, varscan2
- SEMA3E | c.2013G>A p.E671= | Silent (SNP) | VAF 102/254 reads (40%) | catalogued as rs1340292086, COSV57090559; called by muse, mutect2, varscan2
- SLC16A12 | c.1209G>T p.G403= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as COSV57950053; called by muse, mutect2, varscan2
- SLC25A51 | c.165C>T p.L55= | Silent (SNP) | VAF 44/262 reads (17%) | catalogued as rs761495420, COSV54252819; called by muse, mutect2, varscan2
- TASP1 | c.1125G>A p.E375= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV61813083; called by muse, mutect2, varscan2
- TERF2 | c.1101C>T p.A367= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV54747443; called by muse, mutect2, varscan2
- THBS4 | c.1749A>G p.P583= | Silent (SNP) | VAF 119/395 reads (30%) | catalogued as COSV63469369; called by muse, mutect2, varscan2
- THSD1 | c.2289G>A p.P763= | Silent (SNP) | VAF 119/293 reads (41%) | catalogued as rs1215109312, COSV51628586; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824449 C>A | 5'Flank (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640954 G>A | 3'Flank (SNP) | VAF 20/56 reads (36%) | catalogued as rs762726448, COSV51704779; called by muse, mutect2
- MIR873 | n.63C>T | RNA (SNP) | VAF 11/56 reads (20%) | catalogued as rs1247999695; called by muse, mutect2, varscan2
- MSRB3 | c.98-18202_98-18196del | Intron (DEL) | VAF 13/104 reads (13%) | called by mutect2, pindel, varscan2
